Gene-level copy-number profile of tumor specimen HCM-SANG-1323-C15-08A-01D-A80T-32 from HCMI case HCM-SANG-1323-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-1323-C15-08A-01D-A80T-32: Sample type: Post neo-adjuvant therapy; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 017c49fc-c05d-4644-9475-d8d1d1362f61.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1323-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/5cebb3b9-9979-4929-948e-02cce5ab9f02

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,842; copy number 2: 50,748; copy number 3: 5,235; copy number 4: 5; copy number 5: 28; copy number 6: 45; copy number 8: 4; copy number 11: 5; copy number 12: 4.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 86 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:40,512,333–44,066,731, 69 genes, copy number 5–6 (broad region; genes not listed).
- chr12:67,065,018–67,753,817, 13 genes, copy number 6–11 (within-gene range 3–11): AC073530.2, RAB11AP2, GGTA2P, CAND1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1.
- chr12:69,212,108–69,285,485, 4 genes, copy number 12: AC127894.1, CPSF6, MIR1279, C1GALT1P1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
